Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AE02, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AE02-TTP1-A (Primary Tumor).

[page 1 of 16]
Surgical Pathology Report

* Final Report *

Result Type: Surgical Pathology Report

DOS/Dictation Date: +0

Result Status: Auth (Verified)

Result Title: SP Final Report

Performed by:

Verified By:

Encounter info:

* Final Report *

SP Final Report

Patient Name:

Accession Number:

Submitting Physician:

Surgical Pathology Final Report

+3

Date of Service:

Date Received:

Verified:

FINAL DIAGNOSIS

ATTENTION

REPORT OF MALIGNANCY

A. Distal stomach, partial gastrectomy

- Invasive, moderately differentiated, expansile/intestinal adenocarcinoma, extending deeply into muscularis propria and displaying extramural vascular invasion.

- Proximal gastric and distal duodenal margins negative for carcinoma.

- Focally atrophic gastritis with intestinal metaplasia.

- Twenty one(21) lymph nodes negative for carcinoma.

/

B. Left liver lobe, biopsy

- Metastatic adenocarcinoma.

Date dictated:

+3

Printed by:

Printed on:

[page 2 of 16]
Surgical Pathology Report

* Final Report *

SYNOPSIS REPORT

A: STOMACH, RESECTION

SPECIMEN:

Stomach

PROCEDURE: Partial gastrectomy, distal

TUMOR SITE:

Body

*Posterior wall

TUMOR SIZE:

Greatest dimension: 5.5 cm

*Additional dimensions: 4.5 cm

HISTOLOGIC TYPE:

Adenocarcinoma, intestinal type

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC EXTENT OF TUMOR:

Tumor invades muscularis propria (with extramural vascular invasion)

MARGINS:

Proximal margin uninvolved by invasive carcinoma

Distal margin uninvolved by invasive carcinoma

*LYMPH-VASCULAR INVASION:

Present

PATHOLOGIC STAGING (pTNM):

Surgical Pathology Final Report

Date of Service:

+0

pT3: Tumor invades subserosal connective tissue, without involvement of visceral peritoneum or adjacent structures (Extramural vascular invasion)

pN0: No regional lymph node metastasis (21 lymph nodes)

pM1: Distant metastasis

*Specify site(s), if known: Liver

*ADDITIONAL PATHOLOGIC FINDINGS:

*Intestinal metaplasia

* Other gastritis - Focally atrophic

MICROSCOPIC DESCRIPTION

A. The large mass is invasive adenocarcinoma. The adenocarcinoma is moderately differentiated and considered to be expansile/intestinal type.

It extends deeply into muscularis propria, not quite to the serosal surface. Intramural and extramural vascular (likely venous) invasion by the neoplasm is identified. The extramural venous invasion is present in the lesser omentum and focally in the greater omentum. The remaining stomach displays focally atrophic gastritis with intestinal metaplasia.

Proximal, gastric and distal duodenal margins are negative for carcinoma.

Twenty one (21) lymph nodes are negative for carcinoma.

B. This liver nodule is metastatic adenocarcinoma similar to that seen in the stomach (A). Microscopic examination has been performed at

Printed by:

Printed on:

[page 3 of 16]
Surgical Pathology Report
* Final Report *

CLINICAL INFORMATION

A. Distal stomach. Time tissue removed from patient: [REDACTED] Time tissue is placed in fixative: [REDACTED] B. Left lobe of the liver mass. Time tissue removed from patient: [REDACTED] Time tissue is placed in fixative: [REDACTED]

PREOPERATIVE DIAGNOSIS
Gastric CA.

GROSS DESCRIPTION

A. "Distal stomach" This partial gastrectomy specimen measures 18 cm along the greater curvature and 9 cm along the lesser curvature. A 17 x 6 cm portion of omentum is attached to the greater curvature. Posterior serosa is puckered over a 3 x 2 cm area. Upon opening a raised, sessile, firm, fungating mass is 5.5 x 4.5 cm. Located on the posterior wall, near the lesser curvature, 1.5 cm from the proximal mucosal margin and 9.5 cm from the distal mucosa margin. Blue ink is painted on the proximal margin, green on the distal margin, and black ink on the serosal surface. A firm, white 2.5 x 1.2 x 1.0 cm nodule is present in the lesser curvature and appears to be matted lymph nodes. The margins, mass, and lymph nodes are dissected. The remaining gastric mucosa has the usual rugae folds. The distal portion of the stomach has a somewhat cobblestone appearance. On section the mass comprises firm tan tissue which extends the full thickness of the gastric wall.

- 1-2. Gastric margin near mass.
- 3-4. Additional proximal margin.
- 5-6. Distal duodenal margin.

Surgical Pathology Final Report

Date of Service: [REDACTED]

+0

- 7-10. Mass. Representative.
- 11. Additional stomach. Representative.
- 12. Grossly positive nodules, lesser curvature. Representative.
- 13-14. Additional lymph nodes lesser curvature. All.
- 15. Possible diverticulum greater curvature. All.
- 16-18. Lymph nodes greater curvature. All.

B. "Left lobe of liver of mass" This is a 1.5 x 1 x 0.8 cm white nodule. It is trisected. All. Gross examination has been performed at [REDACTED]

[page 5 of 16]
Surgical Pathology Report
* Final Report *

Result Type: Surgical Pathology Report
DOS/Dictation Date: [REDACTED] +0
Result Status: Modified
Result Title: SP Addendum Report
Performed by: [REDACTED]

* Final Report *

SP Addendum Report

Patient Name: [REDACTED]
Accession Number: [REDACTED]
Submitting Physician: [REDACTED]

Surgical Pathology Addendum Report

Verified: [REDACTED] +530

ADDITIONAL INFORMATION

ADDENDUM REPORT - HER2NEU by FISH - ADDED - [REDACTED] +530

A request for HER2NEU by FISH was received on [REDACTED] +524

The case report, slides, and blocks for the cited accession were retrieved from archives. The pathologist whose signature appears below reviewed the original pathology report, examined candidate H&E slides, and selected the block (A10) appropriate to the specifications of the ordered molecular analysis. This block was forwarded to [REDACTED]

[REDACTED] where the subject molecular test was performed. Results were received on [REDACTED] Please see separate laboratory report for details.
+530

Reference Laboratory results are scanned into [REDACTED] under "Documents

Pathology Reports (scanned)" and "Flow Sheet
Pathology Reports
(scanned)".

Date dictated: [REDACTED] +530

ADDENDUM REPORT - HER2NEU BY IHC - ADDED - [REDACTED] +528
A request for HER2NEU by IHC was received on [REDACTED] +524
The case report, slides, and blocks for the cited accession were retrieved from archives. The pathologist whose signature appears below reviewed the

Printed by: [REDACTED]
Printed on: [REDACTED]

[page 6 of 16]
Surgical Pathology Report
* Final Report *

original pathology report, examined candidate H&E slides, and selected the block [REDACTED] appropriate to the specifications of the ordered molecular analysis. This block was forwarded to [REDACTED] where the subject molecular test was performed. Results were received on [REDACTED]. Please see separate laboratory report for details.
+528

Reference Laboratory results are scanned into [REDACTED] under "Documents

Pathology Reports (scanned)" and "Flow Sheet
Pathology Reports
(scanned)".

Date dictated: [REDACTED]

+528

Completed Action List:

[REDACTED]

Printed by:
Printed on:

[REDACTED]

[page 7 of 16]
CT Abd/Pelvis w/ Contrast

* Final Report *

Result Type: CT Abd/Pelvis w/ Contrast
DOS/Dictation Date: -6
Result Status: Auth (Verified)
Result Title: CT Abd/Pelvis w/ Contrast
Performed by: -5
Verified By: -4
Encounter info:

*** Final Report ***

Reason For Exam

Other - Specify in Special Instructions

REPORT

Clinical history is stomach mass from endoscopy.

Multiple axial and reformatted sagittal and coronal images of the abdomen and pelvis were obtained following administration of 75 cc of Isovue 370 intravenous contrast and oral contrast.

Dependent atelectasis is seen at the lower lobes posteriorly. There is no pleural effusion. There is wall thickening of the stomach near the fundal body junction. This may represent the described mass. This thickening extends towards a lumen.

Within the liver there are several heterogeneous appearing ill-defined hypodense regions. The largest is seen at the left hepatic lobe measuring 6 cm in AP dimension. A hyperenhancing area is seen within the right lobe. There are cysts as well. A 1 cm lymph node is seen anterior to the pancreatic head. The spleen is normal in size. The adrenal glands and gallbladder are unremarkable. The kidneys enhance and excrete symmetrically. There is no bowel distention. The appendix is normal in caliber.

IMPRESSION:

There is area of focal wall thickening involving the stomach at the fundal body junction that extends intraluminal. This may represent the described gastric mass. There are multiple ill-defined lesions within the liver suspicious for metastatic disease. This appears amenable to CT-guided biopsy if indicated clinically.

Signature Line

FINAL

Dictated By:

And Verified By:

Electronically Signed Date: -4
Date Transcribed

Printed by:

Printed on:

[page 8 of 16]
CT Abd/Pelvis w/ Contrast
* Final Report *

Printed by:
Printed on:

[page 9 of 16]
CT Thorax w/ Contrast
* Final Report *

Result Type: CT Thorax w/ Contrast
DOS/Dictation Date: [REDACTED] -5
Result Status: Auth (Verified)
Result Title: CT Thorax w/ Contrast
Performed by: [REDACTED]
Verified By: [REDACTED]
Encounter info: [REDACTED]

*** Final Report ***

Reason For Exam
Metastasis

REPORT

EXAMINATION: CT thorax with contrast.

HISTORY: Metastasis

CT scanning was obtained without contrast.

FINDINGS:

There is some thickening of interlobular septae in the lower lobes bilaterally with subpleural sparing, suggesting the possibility of nonspecific interstitial pneumonitis. Some paraseptal pulmonary emphysema is also noted.

There is no evidence of any pulmonary nodules. There is no pulmonary consolidation.

There is no axillary, hilar or mediastinal lymphadenopathy. There is evidence of diffuse hepatic metastases. The visualized upper abdominal viscera appear otherwise unremarkable.

There are no osteolytic or osteoblastic changes.

IMPRESSION:

1. Hepatic metastases.
2. There is no other evidence of metastatic disease.
3. Possible nonspecific interstitial pneumonitis of the lungs.

Signature Line

FINAL

Dictated By:

And Verified By: [REDACTED]

Printed by:
Printed on:

[page 10 of 16]
CT Thorax w/ Contrast
* Final Report *

Electronically Signed Date: [REDACTED]
Date Transcribed [REDACTED]

-5

Completed Action List:

Printed by:
Printed on:

Page 2 of 2
(End of Report)

[page 11 of 16]
[REDACTED]

Jacket Number: [REDACTED]

Date of Service: [REDACTED]

+336

Patient Name: [REDACTED]

Ordering
Physician: [REDACTED]

Date of Birth: [REDACTED]

Examination: CT ABDOMEN WITH CONTRAST

History: 151.8 Hx gastric ca

Multiple contiguous axial CT images were made through the abdomen using intravenous injection of 50 cc of Omnipaque 350 and oral contrast. +237 and +153

Comparison was made to the prior studies the most recent ones [REDACTED]

Lung bases are unremarkable.

Metastases seen involving the left lobe of the liver is no longer visualized or delineated. Small residual hypodensity in the right lobe of the liver again is identified measuring up to 1.5 cm in the longest dimension which has decreased from 2.5 cm on the prior study. Differences in size could also be due to administration of IV contrast and better delineation of the lesion.

No new liver lesion however is identified. Previously seen cysts are unchanged. There is no evidence of intra- or extrahepatic biliary ductal dilatation. Portal vein remains patent.

No enlarged lymph node is seen in the retroperitoneum porta hepatis or gastrohepatic interval. There is no evidence of ascites.

Kidneys excrete contrast without hydronephrosis. Small simple appearing cyst involving the right kidney is unchanged.

Spleen pancreas and adrenal glands are stable without evidence of suspicious or new abnormality.

Bowel gas pattern is nonobstructive.

Visualized osseous structures are unremarkable except for degenerative changes.

IMPRESSION:

1. No new liver lesion and interval further decrease in the size of the residual hypodensity in the right lobe of the liver now measuring 1.5 cm in maximal dimension.. Previously seen lesion in the left lobe of the liver is no longer perceptible. Study is otherwise unchanged

[REDACTED]

[page 12 of 16]
[REDACTED]

Date of Service:
Page 2 of 2

[REDACTED] +336

[REDACTED]

[REDACTED]

[REDACTED]

[page 13 of 16]
CT Abdomen w/ Contrast

* Final Report *

Result Type: CT Abdomen w/ Contrast
DOS/Dictation Date: [REDACTED] +398
Result Status: Auth (verified)
Result Title: CT Abdomen w/ Contrast
Performed by: [REDACTED]
Verified By: [REDACTED]
Encounter info: [REDACTED]

* Final Report *

Reason For Exam

neoplasm of the stomach

REPORT

INDICATION: History of stomach neoplasm

CT imaging of the abdomen was performed following the administration of oral and 75 cc Omnipaque 350 intravenous contrast. Coronal and sagittal reformatted images were reviewed at the workstation. The DLP is 374.65 mGy-cm. Comparison made to prior CT abdomen/pelvis on [REDACTED] -6

There are chronic interstitial changes in the lung bases. No discrete pulmonary nodule or mass in the visualized lung bases. No pleural or pericardial effusion.

There are postoperative changes involving the stomach with no recurrent gastric mass visualized. Multiple low attenuating lesions are seen in the liver, measuring simple fluid density and compatible with cysts. Some hepatic cysts have increased in size since prior study, the largest in the inferior hepatic lobe measuring 4.4 x 2.9 cm. Previously described ill-defined lesions in the liver are no longer visualized. No definite peritoneal or retroperitoneal adenopathy identified.

Gallbladder is not distended. No splenic or pancreatic mass identified. Stable mild nodular thickening of the left adrenal gland. Right adrenal gland appears unremarkable. Kidneys enhance and excrete contrast symmetrically without hydronephrosis. No suspicious renal mass seen. There is a small stable cyst arising from the posterior aspect of the right kidney. No free air or free fluid. Visualized bowel loops are normal in caliber. No suspicious lytic or blastic osseous lesion identified.

IMPRESSION:

1. No convincing evidence of recurrent or metastatic disease.
2. Multiple low attenuating lesions in the liver, some of which are too small to further characterize, which appear to represent cysts. Multiple cysts have increased in size since prior study. Cystic metastasis is considered unlikely.

Workstation: [REDACTED]

Signature Line

Printed by: [REDACTED]
Printed on: [REDACTED]

[page 14 of 16]
CT Abdomen w/ Contrast
* Final Report *

FINAL

Dictated By:

And Verified By:

Electronically Signed Date:

Completed Action List:

Printed by:
Printed on:

[page 15 of 16]
CT Abd/Pelvis w/o Contrast

* Final Report *

Result Type: CT Abd/Pelvis w/o Contrast
DOS/Dictation Date: [REDACTED] +1562
Result Status: Auth (Verified)
Result Title: CT Abd/Pelvis w/o Contrast
Performed by: [REDACTED]
Verified By: [REDACTED]
Encounter info: [REDACTED]

*** Final Report ***

Reason For Exam
Abdominal Pain Lower

REPORT

INDICATION: Initial study for history of lower abdominal pain.

TECHNIQUE: Multiple contiguous axial CT images of the abdomen and pelvis were obtained without IV contrast in the supine position. Automatic exposure software was used. The medical record is properly documented with the dose reduction technique utilized.

Total DLP: 266.52 mGy-cm

FINDINGS:

Platelike dependent atelectasis is seen in the lung bases.

Within the limitations of a noncontrast study, the spleen and gallbladder appears unremarkable. There is mild stable distention seen of the gallbladder. Multiple stable liver cysts are seen. There is significant distention of the stomach which causes impression on the pancreas, left kidney and elevation of the left hemidiaphragm. Prior bypass surgery changes are seen. Visualized portions of the pancreas appears unremarkable.

The kidneys are of normal size without evidence of hydronephrosis or calculi. The urinary bladder appears unremarkable. Moderate amount of stool is noted within the colon. There are no dilated small bowel loops seen to suggest small bowel obstruction. A normal/abnormal appendix is not seen. There is no evidence of free fluid or free air in abdomen. The urinary bladder appears unremarkable. Calcific atheromatous changes are noted within the abdominal aorta without evidence of aneurysmal change. Mild degenerative changes are noted in the lumbar spine.

IMPRESSION:

Distention of the stomach causing elevation of the left hemidiaphragm.
Stable hepatic cysts and stable mild distention of the gallbladder.

I have personally viewed this examination and agree with the interpretation.

Workstation: [REDACTED]

Printed by: [REDACTED]
Printed on: [REDACTED]

[page 16 of 16]
CT Abd/Pelvis w/o Contrast
* Final Report *

Signature Line

FINAL

Dictated By:

And Verified By:

Electronically Signed

PACS Reference Pointer

This document has an image

Completed Action List:

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 3823af78-194a-4f38-b11f-6027d62c9061 (ER0372 ER-AE02 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).